Gene-level copy-number profile of tumor specimen C3L-05478-02 from CPTAC case C3L-05478, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 73.8 years (26,949 days).
Specimen C3L-05478-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1d4d61f-65b5-4136-bbc4-27d68e5d236b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05478-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/21caf9dd-dc86-4f73-8c15-b89fd49b8be0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 117; copy number 2: 3,837; copy number 3: 12,586; copy number 4: 20,041; copy number 5: 7,766; copy number 6: 4,967; copy number 7: 2,260; copy number 8: 4,300; copy number 9: 1,054; copy number 10: 663; copy number 11: 444; copy number 14: 7; copy number 15: 176; copy number 16: 42; copy number 17: 16; copy number 20: 22; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,928,253, 11 genes (within-gene range 0–5): PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:122,628,952–125,602,227, 34 genes: LINC02201, ARGFXP1, SNX2, AC008669.1, SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1, CEP120, KRT8P33, HMGB3P17, AC026422.1, CSNK1G3, KRT18P16, LINC01170, HMGB1P29, AC016556.1, AC025465.2, AC025465.4, AC025465.3, AC025465.1, ZNF608, AC112196.1, AC113398.2, AC113398.1, LINC02240, AC109464.1, AC109464.2, AC109458.1, HMGB1P22.
- chr5:125,350,868–125,968,085, 6 genes: RN7SKP117, AC109471.1, AC116362.2, AC010587.2, AC010587.1, RPSAP37.
- chr15:21,405,401–21,946,641, 28 genes: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:34,379,068–34,437,466, 5 genes (within-gene range 0–1): GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3.
- chr15:34,555,870–34,556,820, 1 gene (within-gene range 0–5): AC027139.1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,425 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–827,796, 51 genes, copy number 10 (within-gene range 8–10): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6, AL669831.4, FAM87B.
- chr1:118,264,372–119,001,405, 6 genes, copy number 15: RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2.
- chr2:82,476,825–83,219,105, 9 genes, copy number 10: AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1.
- chr5:25,701,217–45,895,970, 281 genes, copy number 9–11 (broad region; genes not listed).
- chr6:45,880,827–47,369,230, 22 genes, copy number 11: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2.
- chr7:97,117,698–97,181,763, 2 genes, copy number 9: SDHAF3, HMGB3P21.
- chr8:46,784,800–48,064,708, 36 genes, copy number 11: AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2.
- chr8:72,947,150–75,566,834, 58 genes, copy number 9: AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:79,611,117–87,874,015, 141 genes, copy number 9–11 (broad region; genes not listed).
- chr8:89,412,621–104,484,465, 297 genes, copy number 10–20 (broad region; genes not listed).
- chr8:113,600,310–113,950,998, 2 genes, copy number 11–21: AC103993.1, Y_RNA.
- chr10:14,061–254,637, 7 genes, copy number 10: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:6,682,513–6,823,789, 1 gene, copy number 11 (within-gene range 8–11): AL158210.1.
- chr10:6,737,418–6,840,712, 1 gene, copy number 11 (within-gene range 8–11): AL392086.2.
- chr10:6,779,549–38,360,098, 501 genes, copy number 9–11 (within-gene range 8–12) (broad region; genes not listed).
- chr12:66,950,754–72,728,844, 110 genes, copy number 9–10 (broad region; genes not listed).
- chr13:69,700,594–70,108,493, 1 gene, copy number 9 (within-gene range 6–9): KLHL1.
- chr13:69,894,101–81,691,072, 129 genes, copy number 9 (broad region; genes not listed).
- chr13:83,145,540–114,337,626, 385 genes, copy number 9–11 (broad region; genes not listed).
- chr15:28,519,611–28,685,264, 8 genes, copy number 9: GOLGA8G, Metazoa_SRP, AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2.
- chr18:3,066,807–4,455,307, 27 genes, copy number 9 (within-gene range 7–9): MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr20:18,809,728–19,056,796, 3 genes, copy number 11: SCP2D1-AS1, SCP2D1, AL135936.1.
- chr20:38,581,195–56,005,519, 347 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
